MMRF case MMRF_2560 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a08ab8f6-2bea-4109-92ce-96afbd4be98e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.2 years (23,090 days); Days to last known disease status: 613 days (1.7 years); Days to last follow up: 613 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 11 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 74 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 137 days; Days to treatment end: 137 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -32 (ECOG 0): M Protein 4.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Hemoglobin 7.25 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.1 mmol/L; Albumin 33 g/L; Total Protein 10.5 g/dL; Glucose 4.9 mmol/L.
- Day 43 (ECOG 0): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.546 mg/dL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 8.5 g/dL; Glucose 7.04 mmol/L.
- Day 152: M Protein 1.2 g/dL; Lactate Dehydrogenase 3.77 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 96 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 1.79 mmol/L; Calcium 2.15 mmol/L; Albumin 29 g/L; Total Protein 6.4 g/dL; Glucose 5.28 mmol/L.
- Day 228 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.801 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.948 mg/dL; Immunoglobulin G 9.74 g/L; Immunoglobulin A 0.209 g/L; Immunoglobulin M 0.154 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 13 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 5.06 mmol/L.
- Day 320 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.91 mg/dL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 365 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.35 mmol/L; Albumin 33 g/L; Total Protein 7.9 g/dL; Glucose 5.56 mmol/L.
- Day 411 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.86 mg/dL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 7.5 g/dL; Glucose 5.45 mmol/L.
- Day 494 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.54 mg/dL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 7.7 g/dL; Glucose 5.34 mmol/L.
- Day 613 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.97 mg/dL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 7.1 g/dL; Glucose 5.12 mmol/L.

Other clinical attributes
- Day -32: Weight: 73 kg; Height: 190 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2560_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -32 days.
- Sample MMRF_2560_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -32 days.
